Somatic mutation profile of tumor specimen ALCH-B3DG-TTP1-A (aliquot ALCH-B3DG-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B3DG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 81.0 years (29,569 days).
Specimen ALCH-B3DG-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 262cbbb2-bee2-4deb-b549-17fb54b38696.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3DG-NB1-A (Blood Derived Normal), aliquot ALCH-B3DG-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b89633e0-2b25-4315-837e-19d53458e53a

The open-access MAF lists 72 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 14, Intron 5, Nonsense Mutation 4, 5'UTR 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHCTF1 | c.1936C>T p.H646Y (on ENST00000366508; = p.H620Y on NM_015446.5) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as COSV100403376; called by muse, mutect2
- BTK | c.1745C>A p.A582D | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CD984185, CM097794, CM950174, COSV58118788; called by muse, mutect2
- CEP128 | c.1332C>G p.I444M | Missense Mutation (SNP) | VAF 20/558 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as rs1243724659; called by muse, mutect2
- DIP2C | c.1586G>C p.G529A | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1413860424; called by muse, mutect2
- FZD9 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59990241; called by muse, mutect2
- IGHG3 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.364); catalogued as rs769456444; called by muse, mutect2
- L1CAM | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as CD972291, COSV100648893; called by muse, mutect2, varscan2
- NUDCD1 | c.1441G>C p.A481P | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53454423; called by muse, mutect2
- P2RY10 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as rs200750596, COSV50682648; called by muse, mutect2
- PAOX | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 30/470 reads (6%) | catalogued as rs369970251; called by muse, mutect2
- RBL1 | c.1840A>G p.M614V | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs375434002; called by muse, mutect2
- RUSF1 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs1361241714; called by muse, mutect2
- SLC22A7 | c.658G>C p.E220Q (on ENST00000372585 / NM_153320.2; = p.E218Q on NM_006672.3) | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.884); catalogued as rs1253488027; called by muse, mutect2
- TET2 | c.5734C>T p.H1912Y | Missense Mutation (SNP) | VAF 31/334 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs556198889, COSV54396009; called by muse, mutect2
- TGIF2LX | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 43/391 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as rs1217742625; called by muse, mutect2
- ACR | c.698T>C p.I233T | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- APOL6 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.817); called by muse, mutect2
- CCDC150 | c.892+5G>A | Splice Region (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- COL1A2 | c.70T>C p.S24P | Missense Mutation (SNP) | VAF 21/616 reads (3%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.026); called by muse, mutect2
- CORO2B | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.99); called by muse, mutect2
- CYLC1 | c.1853C>G p.S618* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- DENND2A | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- DHX16 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- EDNRB | c.1324C>T p.Q442* (on ENST00000377211 / NM_001201397.1; = p.Q352* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 19/495 reads (4%) | called by muse, mutect2
- GPR158 | c.3542A>T p.Q1181L | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- HM13 | c.991G>T p.V331F | Missense Mutation (SNP) | VAF 18/375 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2
- ITPRID2 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- KCND2 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2
- LMO7 | c.2591C>G p.S864C (on ENST00000357063; = p.S545C on NM_005358.5) | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- MEGF6 | c.2918G>T p.G973V | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYH7B | c.5588T>C p.L1863P | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- NOP58 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NPPA | c.110T>A p.L37Q | Missense Mutation (SNP) | VAF 32/639 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR52L1 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PCBP1 | c.222G>C p.M74I | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2
- PLXNA4 | c.862A>T p.T288S | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.388); called by muse, mutect2
- PNLIPRP2 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); called by muse, mutect2
- PRPF3 | c.1629A>G p.I543M | Missense Mutation (SNP) | VAF 15/345 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2
- PTPRK | c.1382C>T p.T461I | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); called by muse, mutect2
- SATL1 | c.904C>A p.P302T (on ENST00000395409; = p.P489T on NM_001012980.2) | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); called by muse, mutect2
- SLC6A5 | c.2093A>G p.Y698C | Missense Mutation (SNP) | VAF 10/312 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.586); called by muse, mutect2
- SLCO2A1 | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- SPRY3 | c.211C>G p.Q71E | Missense Mutation (SNP) | VAF 11/316 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.02); called by muse, mutect2
- TM9SF4 | c.1670A>T p.Y557F | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM100 | c.129G>T p.M43I | Missense Mutation (SNP) | VAF 17/413 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2
- TUBGCP6 | c.3664A>T p.S1222C | Missense Mutation (SNP) | VAF 37/503 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2
- USH2A | c.8933A>T p.D2978V | Missense Mutation (SNP) | VAF 12/390 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2
- VN1R1 | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.472); called by muse, mutect2
- WAPL | c.1176G>T p.L392F | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2
- ZFHX2 | c.2840C>A p.P947H | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0.01); called by muse, mutect2
- ACTN2 | c.1338G>T p.A446= | Silent (SNP) | VAF 22/374 reads (6%) | catalogued as rs397516566, COSV63971577, COSV63972576; called by muse, mutect2
- CCDC39 | c.2484T>G p.L828= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as CD124798; called by mutect2, varscan2
- CDCP1 | c.489C>A p.I163= | Silent (SNP) | VAF 21/312 reads (7%) | called by muse, mutect2
- DUOXA1 | c.258A>T p.S86= | Silent (SNP) | VAF 12/330 reads (4%) | called by muse, mutect2
- HTR2C | c.774A>G p.G258= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- KARS1 | c.1029C>T p.A343= | Silent (SNP) | VAF 43/675 reads (6%) | called by muse, mutect2
- MBTPS1 | c.801T>G p.A267= | Silent (SNP) | VAF 14/344 reads (4%) | called by muse, mutect2
- MUC16 | c.27423C>T p.A9141= | Silent (SNP) | VAF 10/226 reads (4%) | catalogued as rs1437337196; called by muse, mutect2
- NCKAP5 | c.897T>C p.D299= | Silent (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- OR52L1 | c.372A>T p.A124= | Silent (SNP) | VAF 17/393 reads (4%) | catalogued as rs1468134780; called by muse, mutect2
- OR5D14 | c.561C>T p.I187= | Silent (SNP) | VAF 20/326 reads (6%) | catalogued as rs1376852689, COSV59458705; called by muse, mutect2
- PPP1R11 | c.291A>G p.G97= | Silent (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- PTPRN | c.171C>A p.G57= | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- THSD1 | c.1512A>T p.V504= | Silent (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- AP001007.2 | n.456A>G | RNA (SNP) | VAF 16/264 reads (6%) | called by muse, mutect2
- BRAF | c.609-245G>T | Intron (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- OR8A1 | c.-9C>A | 5'UTR (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- PTMS | c.-181C>T | 5'UTR (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- RNASEH2B | c.742-44G>T | Intron (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- TDP1 | c.1753+126A>T | Intron (SNP) | VAF 26/338 reads (8%) | called by muse, mutect2
- TTLL4 | c.3187+34T>G | Intron (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- UGT3A1 | c.843+2457C>T | Intron (SNP) | VAF 11/260 reads (4%) | called by muse, mutect2
